Gene-level copy-number profile of tumor specimen TCGA-AZ-6608-01A from TCGA case TCGA-AZ-6608, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 55.0 years (20,094 days).
Specimen TCGA-AZ-6608-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.3890221a-9701-41ba-8e20-6f5833cd9e3e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AZ-6608-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8492f902-0029-4521-9756-bd147fb34311

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 793; copy number 2: 8,608; copy number 3: 27,903; copy number 4: 13,895; copy number 5: 4,221; copy number 6: 2,469; copy number 7: 1,703; copy number 8: 141; copy number 9: 86.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AZ-6608-01): tumor purity 0.89, ploidy 3.38, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,930 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–53,127,673, 749 genes, copy number 7–8 (within-gene range 3–8) (broad region; genes not listed).
- chr5:54,048,007–54,075,583, 2 genes, copy number 8: RN7SL801P, AC016601.1.
- chr5:54,643,557–56,321,397, 51 genes, copy number 8: AC016583.1, AC016583.2, CSPG4BP, AC112198.1, AC112198.3, AC112198.2, ESM1, AC034238.1, GZMK, Y_RNA, AC034238.3, AC034238.2, GZMAP1, GZMA, CDC20B, GPX8, MIR449A, MIR449B, MIR449C, MCIDAS, CCNO, AC026704.1, DHX29, MTREX, AC020728.1, PLPP1, AC010480.1, MIR5687, RNF138P1, AK4P2, SLC38A9, DDX4, AC016632.1, RNA5SP183, HNRNPH1P3, IL31RA, IL6ST, AC008914.1, AC016596.2, AC008892.1, FLJ31104, AC016596.1, ANKRD55, RNU6-299P, RPL17P22, RNA5SP184, C1GALT1P2, RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1.
- chr5:61,610,424–62,628,582, 13 genes, copy number 8 (within-gene range 3–8): C5orf64, AC026746.1, RNU6-913P, C5orf64-AS1, AC026434.1, AC008877.1, RN7SKP157, KIF2A, AC114982.2, DIMT1, IPO11, RNU6-661P, CKS1BP3.
- chr8:99,796,615–102,124,907, 63 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr20:19,208,652–45,843,276, 632 genes, copy number 7–9 (broad region; genes not listed).
- chr20:46,859,333–64,313,132, 420 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 793. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
